Surgical pathology report (de-identified scan), TCGA case TCGA-ER-A19Q, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Pittsburgh, specimen TCGA-ER-A19Q-06A (Metastatic).

105-0-3

Melanoma, NOS 8720/3 12/15/10 *lw*

Site Code: groin, skin C44.5

PATIENT HISTORY:

The patient is a year old woman with a history of metastatic melanoma.

PRE-OP DIAGNOSIS: Metastatic melanoma.

POST-OP DIAGNOSIS: Same.

PROCEDURE: Left groin dissection.

FINAL DIAGNOSIS:

SKIN AND SOFT TISSUE, LEFT GROIN, DISSECTION

- A. METASTATIC MELANOMA INVOLVING SOFT TISSUE (10 CM) AND ONE OF FOUR LYMPH NODES (1/4).
- B. SKIN WITH SCAR (PREVIOUS BIOPSY SITE).

Source: NCI Genomic Data Commons file a64a71c0-f7c2-4951-86fb-033d26b6cf2c (TCGA-ER-A19Q.9D272406-BF65-4CF2-BF52-620EFC21E209.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).